Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JJ-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. RIGHT KIDNEY CORE BIOPSY:
Positive for carcinoma.
- B. RIGHT KIDNEY, NEPHRECTOMY:
Renal cell carcinoma, papillary type II. See Key Pathologic Findings.
Surgical margins, free of malignancy.
Pathologic stage: pT1a NX MX.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

There are focal mucinous changes.

Ancillary Studies

Immunoperoxidase stains (cytokeratin 7, cytokeratin 20, AMACR and vimentin) performed with appropriate positive and negative controls on block B10 support the diagnosis.

Key Pathological Findings

B: Kidney Resection

PROCEDURE:

SPECIMEN TYPE: Nephrectomy

SPECIMEN LATERALITY:

Right

TUMOR SIZE (largest tumor if multiple):

Dimension: 3.0 cm

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal cell carcinoma

SARCOMATOID FEATURES:

Not identified

TUMOR NECROSIS:

Present < 5 %

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 microns; nucleoli large and prominent

MICROSCOPIC TUMOR EXTENSION:

Tumor limited to kidney

MARGINS:

Vascular, ureteral and surgical margins, uninvolved by carcinoma

ADRENAL GLAND:

ICD-O-3

Carcinoma, papillary renal
cell 8260/3

Site: @ Kidney NOS C64.9

9/24/28/14

[page 2 of 3]
Not present
PERINEURAL INVASION:
Absent
ANGIOLYMPHATIC INVASION:
Absent
LYMPH-VASCULAR INVASION:
Absent
PRIMARY TUMOR (pT):
pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM):
pMX

Specimen(s) Received

A CORE BIOPSY RIGHT KIDNEY FS
B RIGHT NEPHRECTOMY

Preoperative Diagnosis

Right renal mass.

Frozen Section Diagnosis

FSA1 AND TOUCH IMPRINT: CORE BIOPSY OF RIGHT KIDNEY:
Positive for carcinoma.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____ M.D., have performed the intraoperative consultation (s) and issued the above diagnosis.

Gross Description

A. The specimen is received fresh in 2 containers. Specimen A is labeled, "core biopsy, right kidney". The specimen consists of 3 core biopsy fragments of pink-tan tissue which are ranging from 1.5 to 2.5 cm in length. Touch and print of the specimen is prepared for cytological evaluation. The specimen is submitted entirely for frozen section as FSA1.

B. Specimen B is labeled, "right nephrectomy". The specimen consists of a partial nephrectomy which measures 4.5 x 3.5 x 3 cm, weight 26g. The renal capsule is tan-red, brown, focally hemorrhagic, smooth and glistening. Prior to sectioning, the specimen is inked as follows:

Parenchymal resection margin: Black.
Capsular surface: Blue.

The specimen is serially sectioned to reveal an irregular to roughly ovoid, ill defined, rubbery intraparenchymal tumor which measures 3 x 2.5 x 2.5 cm. The tumor bulges capsule and partially involves central area of the parenchymal resection margin. Cut surface of the tumor is tan-gray to pink, focally hemorrhagic, without evidence of necrosis. Also received in the same container,

[page 3 of 3]
completion nephrectomy specimen including a kidney (10.5 x 5.5 x 3.5 cm, weight 116 g) which is surrounded by perinephric adipose tissue ranging from 1 to 2.5 cm in thickness. There is a 3 cm length of ureter attached to the kidney, which is grossly unremarkable. There is a partial nephrectomy site on the lateral aspect of the kidney measuring 4 x 3.5 x 2.5 cm. Prior to sectioning, the specimen is inked as follows:

Perinephric adipose resection margin: Orange.
Renal capsule surrounding partial nephrectomy site: Black.
Deep aspect of the partial nephrectomy site: Black.

The deep aspect of the partial nephrectomy site extends to the renal pelvis, partially involving it. The urothelium of the renal pelvis adjacent to the nephrectomy site is focally hemorrhagic. No residual tumor is grossly identified within the renal parenchyma and renal pelvis adjacent to the partial nephrectomy site. The remaining renal parenchyma and urothelium of the caliceal system, renal pelvis, and a portion of the ureter are grossly unremarkable. The renal artery, renal vein and their branches are grossly unremarkable and do not appear to be involved by the tumor. No lymph nodes are grossly identified within the hilar adipose tissue. No adrenal gland is found within the perinephric adipose tissue. Representative sections of the specimen were submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 23 cassettes, as follows:

B1: Resection margin of the ureter, tangential section.
B2: Resection margins of the renal artery and vein, tangential sections.
B3 and B4: Perinephric adipose tissue resection margin closest to the tumor,

perpendicular cross sections.

B5-B12: Representative sections of the tumor, bulging capsule, and involving the deep aspect of nephrectomy specimen.

B13-B18: Deep aspect of the partial nephrectomy site adjacent to the tumor with a portion of renal pelvis.

B19-B22: Additional sections of the deep aspect of partial nephrectomy site.
B23: Grossly unremarkable renal parenchyma.

Source: NCI Genomic Data Commons file add1509d-b373-4aa4-a17e-a24b4eebddbf (TCGA-2Z-A9JJ.56907DFB-EB0B-4906-9DEC-781A9BA80542.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).